Somatic mutation profile of tumor specimen 0DG0G8 from CCDI case PBBRLH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Sertoli-Leydig cell tumor, poorly differentiated, with heterologous elements; Tissue or organ of origin: Ovary; Age at diagnosis: 14.6 years (5,335 days).
Specimen 0DG0G8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bbf4d44b-0970-4fe1-991d-0abb1caee17d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFYPL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/405bb3fd-ef1e-4315-a73a-9b183f0df5ff

The open-access MAF lists 16 somatic variants for this specimen: 8 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 5, RNA 1, Intron 1, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5438A>G p.E1813G | Missense Mutation (SNP) | VAF 836/975 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58615258, COSV58615306, COSV58615741; called by muse, mutect2, varscan2
- DRG2 | c.983G>A p.S328N | Missense Mutation (SNP) | VAF 270/676 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs1225517818; called by muse, mutect2, varscan2
- C6orf58 | c.770T>C p.I257T | Missense Mutation (SNP) | VAF 49/1126 reads (4%) | SIFT tolerated (0.65); PolyPhen benign (0.084); called by muse, mutect2
- ERAS | c.410C>A p.T137N | Missense Mutation (SNP) | VAF 106/234 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- GRM5 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 38/1018 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2
- MRC2 | c.1882G>A p.G628R | Missense Mutation (SNP) | VAF 30/511 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TECPR2 | c.2005G>A p.A669T | Missense Mutation (SNP) | VAF 28/780 reads (4%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.039); called by muse, mutect2
- TEX101 | c.634C>T p.Q212* (on ENST00000598265 / NM_001130011.3; = p.Q230* on NM_031451.4) | Nonsense Mutation (SNP) | VAF 18/390 reads (5%) | called by muse, mutect2
- BPIFA3 | c.210A>C p.A70= | Silent (SNP) | VAF 346/800 reads (43%) | catalogued as rs565577075; called by muse, mutect2, varscan2
- MUC22 | c.4875C>A p.T1625= | Silent (SNP) | VAF 330/834 reads (40%) | catalogued as rs1404552427; called by muse, mutect2, varscan2
- PIK3C2A | c.261A>G p.A87= | Silent (SNP) | VAF 401/1007 reads (40%) | catalogued as rs139422463; called by muse, mutect2, varscan2
- SMR3B | c.189T>C p.P63= | Silent (SNP) | VAF 185/737 reads (25%) | catalogued as rs1250906883; called by muse, mutect2, varscan2
- SV2B | c.1458T>C p.D486= | Silent (SNP) | VAF 517/1245 reads (42%) | called by muse, mutect2, varscan2
- NBEAP2 | n.893G>C | RNA (SNP) | VAF 47/884 reads (5%) | called by muse, mutect2
- SUGP2 | c.-40G>T | 5'UTR (SNP) | VAF 96/198 reads (48%) | called by muse, mutect2
- TCIRG1 | c.1887+68G>A | Intron (SNP) | VAF 84/195 reads (43%) | called by muse, mutect2, varscan2
